Somatic mutation profile of tumor specimen TCGA-DX-A6B8-01A (aliquot TCGA-DX-A6B8-01A-11D-A307-09) from TCGA case TCGA-DX-A6B8, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Liposarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 80.8 years (29,513 days).
Specimen TCGA-DX-A6B8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 818c40af-b6bb-44cd-b8f4-717567ff09da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6B8-10A (Blood Derived Normal), aliquot TCGA-DX-A6B8-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb51e17e-35c3-4189-b105-ade8a2ffc5f5

The open-access MAF lists 51 somatic variants for this specimen: 36 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 31, Silent 15, Frame Shift Ins 2, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.216dup p.V73Rfs*76 | Frame Shift Ins (INS) | VAF 31/51 reads (61%) | catalogued as rs730882018, COSV104369723; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ANO8 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV99343992; called by muse, mutect2, varscan2
- ATRX | c.3337G>T p.E1113* | Nonsense Mutation (SNP) | VAF 15/15 reads (100%) | catalogued as COSV100969916, COSV100970742; called by muse, mutect2, varscan2
- CECR2 | c.782G>A p.R261H (on ENST00000342247 / NM_001290047.2; = p.R98H on NM_001290046.1) | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760539949, COSV52835916; called by muse, mutect2, varscan2
- DOCK8 | c.2482G>A p.A828T | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs138519226; called by muse, mutect2, varscan2
- EDEM2 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as COSV100993626; called by muse, mutect2, varscan2
- FAM131B | c.968T>C p.F323S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100577652; called by muse, mutect2, varscan2
- FBXO5 | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.79); PolyPhen benign (0.024); catalogued as rs1335881589, COSV99999633; called by muse, mutect2, varscan2
- FLAD1 | c.271_272insT p.R91Mfs*11 | Frame Shift Ins (INS) | VAF 15/42 reads (36%) | catalogued as COSV99421973; called by mutect2, pindel, varscan2
- GRIN2D | c.2438A>G p.D813G | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99474175; called by muse, mutect2, varscan2
- GSDMD | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV99369092; called by muse, mutect2, varscan2
- GSDMD | c.323C>A p.A108D | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99369100; called by muse, mutect2, varscan2
- HERC2 | c.9569G>C p.S3190T | Missense Mutation (SNP) | VAF 57/65 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99870421; called by muse, mutect2, varscan2
- HMGB1 | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1225148656, COSV58104747; called by muse, mutect2, varscan2
- HYDIN | c.13391A>G p.Q4464R | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV101124828; called by muse, mutect2, varscan2
- IGHV4-39 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as rs587658234; called by muse, mutect2, varscan2
- LAMB3 | c.2450G>A p.R817H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs747157392, COSV100620065; called by muse, mutect2, varscan2
- LRP2 | c.311-2A>G p.X104_splice | Splice Site (SNP) | VAF 12/13 reads (92%) | catalogued as COSV99786243; called by muse, mutect2, varscan2
- MAP3K11 | c.1382T>A p.L461Q | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100482156; called by muse, varscan2
- MAP3K21 | c.888G>A p.W296* | Nonsense Mutation (SNP) | VAF 18/19 reads (95%) | catalogued as rs1421396237, COSV100786207; called by muse, mutect2, varscan2
- MCAM | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs560440649, COSV50630135; called by muse, mutect2, varscan2
- MMRN1 | c.1718A>C p.K573T | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99306321; called by muse, mutect2, varscan2
- OR52L1 | c.371C>A p.A124E | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100176000; called by muse, mutect2, varscan2
- PACS2 | c.854A>G p.D285G | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100330574; called by muse, mutect2, varscan2
- PCDH11Y | c.562T>A p.S188T (on ENST00000400457 / NM_032973.2; = p.S177T on NM_032971.3) | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.557); catalogued as COSV99290380; called by muse, mutect2, varscan2
- PPIP5K2 | c.2142G>T p.K714N | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100383384; called by muse, mutect2, varscan2
- PRTN3 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as rs551079189, COSV99311429; called by muse, mutect2, varscan2
- S100A7L2 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749908678, COSV64195804; called by muse, mutect2, varscan2
- SCN1A | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as rs755598644, COSV100319026; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SND1 | c.995C>A p.P332H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV100689592; called by muse, mutect2, varscan2
- SNED1 | c.1585T>C p.C529R | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60026381; called by muse, mutect2, varscan2
- SYT16 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761346026, COSV70855321; called by muse, mutect2, varscan2
- TAF1L | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs764175922, COSV54267502, COSV99644025; called by muse, mutect2, varscan2
- USP9Y | c.3634G>A p.E1212K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs868569228, COSV100168169; called by muse, mutect2
- VPS16 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs748567903, COSV100988241; called by muse, mutect2, varscan2
- YY1 | c.709G>C p.V237L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV99216631; called by muse, mutect2, varscan2
- ADGRF2 | c.1176A>G p.T392= (on ENST00000296862 / NM_001368115.2; = p.T324= on NM_153839.7) | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1369513567, COSV99730600; called by muse, mutect2, varscan2
- CALHM1 | c.799C>T p.L267= | Silent (SNP) | VAF 35/36 reads (97%) | catalogued as COSV99588218; called by muse, mutect2, varscan2
- CTNND2 | c.2250G>A p.A750= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as rs778573833, COSV100470947; called by muse, mutect2, varscan2
- DMGDH | c.1158G>A p.Q386= | Silent (SNP) | VAF 23/34 reads (68%) | catalogued as rs1438117311, COSV99668370; called by muse, mutect2, varscan2
- DYNC1H1 | c.8862C>T p.N2954= | Silent (SNP) | VAF 31/36 reads (86%) | catalogued as rs755723273, COSV100794312; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM3D | c.309C>T p.I103= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs763911444, COSV100716682; called by muse, mutect2, varscan2
- MBD1 | c.1158G>T p.L386= (on ENST00000269468 / NM_001323950.1; = p.L330= on NM_002384.2) | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV99495305; called by muse, mutect2, varscan2
- OR4X2 | c.651G>C p.L217= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100183141; called by muse, mutect2, varscan2
- PATJ | c.1044T>G p.T348= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV100332991; called by muse, mutect2, varscan2
- PCDHB1 | c.660G>A p.P220= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs782104351, COSV60631752; called by muse, mutect2, varscan2
- PCDHB9 | c.2019C>G p.L673= | Silent (SNP) | VAF 43/97 reads (44%) | catalogued as rs781917451; called by muse, mutect2, varscan2
- POU4F2 | c.498G>A p.A166= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs1402442561, COSV99850239; called by muse, mutect2, varscan2
- TAS1R2 | c.570C>T p.H190= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs781549433, COSV100946123; called by muse, mutect2, varscan2
- TESK2 | c.1203T>G p.P401= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV100516999; called by muse, mutect2, varscan2
- THAP11 | c.537T>C p.T179= | Silent (SNP) | VAF 14/15 reads (93%) | catalogued as COSV99534168; called by muse, mutect2, varscan2
